Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UP-01A (Primary Tumor).

ICD-O-3

Adenocarcinoma, mucinous
endocervical type 8482/3

Site: Cervix NOS 053.9

3/7/14

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Infiltrative poorly differentiated carcinoma.

Note: Immunohistochemistry exam requested to improve evaluation.

Immunohistochemistry exam

Morphologic aspects associated with the immunohistochemistry profile are compatible with poorly differentiated endocervical mucinous adenocarcinoma.

Source: NCI Genomic Data Commons file af83a548-924a-44b1-a750-b1b25b500067 (TCGA-VS-A9UP.CA4BC8DE-D4C5-4B10-AB82-8A0C766C529F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).